Somatic mutation profile of tumor specimen TCGA-NC-A5HR-01A (aliquot TCGA-NC-A5HR-01A-21D-A26M-08) from TCGA case TCGA-NC-A5HR, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.6 years (27,629 days).
Specimen TCGA-NC-A5HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c67c3019-0bb4-4b0d-bcc6-cb04539fca97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HR-10A (Blood Derived Normal), aliquot TCGA-NC-A5HR-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2683954a-faef-431d-8774-e8600a82489a

The open-access MAF lists 357 somatic variants for this specimen: 280 protein-altering or splice-affecting, 69 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 69, Nonsense Mutation 20, Splice Site 9, Frame Shift Del 9, RNA 4, Nonstop Mutation 2, 3'Flank 2, Splice Region 2, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAT | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912822, CM014854, COSV100339471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 41/79 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.469_476del p.V157Hfs*21 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | catalogued as rs1555526137; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AC244197.3 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100557764; called by muse, mutect2, varscan2
- ACACB | c.2863G>A p.G955S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100622103; called by muse, mutect2, varscan2
- ACAN | c.7069G>A p.V2357I (on ENST00000560601 / NM_001369268.1; = p.V2281I on NM_001135.3) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.474); catalogued as COSV100716669; called by muse, mutect2, varscan2
- ACO2 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV99346910; called by muse, mutect2, varscan2
- ACSM4 | c.954C>A p.C318* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV101256920; called by muse, mutect2, varscan2
- ADAMTS12 | c.4277C>A p.A1426E | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100710045; called by muse, mutect2, varscan2
- ADGRF5 | c.3056G>T p.G1019V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344587; called by muse, mutect2, varscan2
- ADGRV1 | c.7370C>T p.A2457V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs864309625, COSV101315269, COSV67983572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.7054G>C p.G2352R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.106); catalogued as COSV52150780; called by muse, mutect2, varscan2
- ANK2 | c.10702C>T p.R3568W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs72556376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKMY2 | c.1142-2A>G p.X381_splice | Splice Site (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100186777; called by muse, mutect2, varscan2
- APBB1IP | c.900G>C p.E300D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV100881905; called by mutect2, varscan2
- ARHGEF9 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99491197; called by muse, mutect2, varscan2
- ARSB | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs201928777, COSV53730262; called by muse, mutect2, varscan2
- ASPSCR1 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs986220755, COSV100144645; called by muse, mutect2, varscan2
- ATP13A5 | c.3397-1G>A p.X1133_splice | Splice Site (SNP) | VAF 55/276 reads (20%) | catalogued as COSV99290479; called by muse, mutect2, varscan2
- ATP8B4 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV99462769; called by muse, mutect2
- BAG4 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 37/432 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99781669; called by muse, mutect2
- BMPER | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99778533; called by muse, mutect2, varscan2
- BRCA2 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1064794018, COSV101203795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf71 | c.1725C>A p.D575E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100109425; called by muse, mutect2, varscan2
- C22orf42 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.765); catalogued as COSV101173262, COSV66075997; called by muse, mutect2
- C3orf14 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99223638; called by muse, mutect2, varscan2
- CACNA2D1 | c.2713G>T p.E905* (on ENST00000356253 / NM_001366867.1; = p.E893* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 36/148 reads (24%) | catalogued as rs1554330635, COSV100665149; called by muse, mutect2, varscan2
- CASP8 | c.908A>T p.D303V (on ENST00000432109 / NM_033355.3; = p.D320V on NM_001228.4) | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99629570, COSV99630812; called by muse, mutect2, varscan2
- CCDC181 | c.842A>T p.H281L | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100890214; called by muse, mutect2, varscan2
- CCDC34 | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV100156326; called by muse, mutect2, varscan2
- CCDC63 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100370104; called by muse, mutect2, varscan2
- CDH7 | c.9G>T p.L3F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.202); catalogued as COSV100541131; called by muse, mutect2, varscan2
- CDH7 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474589509, COSV100541133; called by muse, mutect2, varscan2
- CDKN2A | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD111993, CD961883, CM960271, COSV58683653, COSV58684450, COSV58705440; called by muse, mutect2, varscan2
- CFAP44 | c.2392G>A p.V798I | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV99868655; called by muse, mutect2, varscan2
- CFAP61 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV99842480; called by muse, mutect2, varscan2
- CFAP61 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs375676702; called by muse, mutect2, varscan2
- CFHR2 | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV100804194, COSV66380861; called by muse, mutect2, varscan2
- CHEK1 | c.815-1G>A p.X272_splice | Splice Site (SNP) | VAF 26/89 reads (29%) | catalogued as COSV54024160; called by muse, mutect2, varscan2
- CHM | c.1331G>T p.C444F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV100752913, COSV100753578; called by muse, mutect2, varscan2
- CLPB | c.1601T>A p.I534N | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99577408; called by muse, mutect2, varscan2
- CLVS2 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.978); catalogued as COSV99251904; called by muse, mutect2, varscan2
- CNBD1 | c.517A>T p.K173* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV101575261; called by muse, mutect2, varscan2
- CNGA4 | c.676A>T p.T226S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101171702; called by muse, mutect2, varscan2
- CNTN6 | c.3082A>G p.I1028V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs780608778, COSV100609591; called by muse, mutect2, varscan2
- COL4A3 | c.2036T>A p.L679Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as COSV101169719; called by muse, mutect2, varscan2
- CRACD | c.1983C>G p.S661R | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV99948283; called by muse, mutect2, varscan2
- CSMD1 | c.3091T>A p.Y1031N (on ENST00000520002; = p.Y1030N on NM_033225.6) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100141539; called by muse, mutect2, varscan2
- CSMD3 | c.10544C>A p.T3515N (on ENST00000297405 / NM_001363185.1; = p.T3346N on NM_052900.3) | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1431214778, COSV99820279; called by muse, mutect2, varscan2
- CSPG4 | c.388A>C p.N130H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100413181; called by muse, mutect2, varscan2
- CTNNA2 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV100781190, COSV63545002, COSV63606583; called by muse, mutect2, varscan2
- CTNNA3 | c.1537C>A p.H513N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101044492; called by muse, mutect2
- CYB5R2 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV100207319; called by muse, mutect2, varscan2
- DCAF4L2 | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60477907; called by muse, mutect2, varscan2
- DCLK1 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV99708397; called by muse, mutect2, varscan2
- DDX19A | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100156086; called by muse, mutect2, varscan2
- DENND4B | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100768301; called by muse, mutect2, varscan2
- DLD | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV99226686; called by muse, mutect2, varscan2
- DOCK5 | c.3734A>T p.Y1245F | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV99375755; called by muse, mutect2, varscan2
- DSCAM | c.4964C>A p.T1655N | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV101258620, COSV68021224; called by muse, mutect2, varscan2
- EBI3 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV99695996; called by muse, mutect2, varscan2
- EFHD1 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV99898227; called by muse, mutect2, varscan2
- EP300 | c.4328G>T p.G1443V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54326008, COSV99606959; called by muse, mutect2, varscan2
- EPB41L3 | c.3190C>A p.H1064N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100547912; called by muse, mutect2, varscan2
- F5 | c.3979C>A p.H1327N | Missense Mutation (SNP) | VAF 202/408 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100888810; called by muse, mutect2, varscan2
- FABP1 | c.241-1G>A p.X81_splice | Splice Site (SNP) | VAF 58/148 reads (39%) | catalogued as rs1336922199, COSV99860687; called by muse, mutect2
- FAM110C | c.946+2T>A p.X316_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as rs1159654112, COSV100566797; called by muse, mutect2, varscan2
- FAM135B | c.2926C>A p.P976T | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.018); catalogued as COSV99417072; called by muse, mutect2, varscan2
- FAM135B | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99355956, COSV99356344; called by muse, mutect2, varscan2
- FAM47C | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100792216, COSV63727084; called by muse, mutect2, varscan2
- FANCD2 | c.3649G>A p.D1217N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as COSV99810031; called by muse, mutect2, varscan2
- FAP | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 84/140 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99501466; called by muse, mutect2, varscan2
- FBXO40 | c.1862G>C p.W621S | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100572870; called by muse, mutect2, varscan2
- FBXO40 | c.1863G>T p.W621C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs528828647, COSV100572871, COSV57526382; called by muse, mutect2, varscan2
- FKBP5 | c.903A>T p.E301D | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as COSV100615944; called by muse, mutect2, varscan2
- FLRT2 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); catalogued as COSV100419852; called by muse, mutect2, varscan2
- FLT3 | c.1969G>C p.A657P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99606885; called by muse, mutect2, varscan2
- FMN2 | c.5090A>G p.Q1697R | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV100141839; called by muse, mutect2, varscan2
- FOXD4L1 | c.429C>A p.Y143* | Nonsense Mutation (SNP) | VAF 145/444 reads (33%) | catalogued as COSV99380057; called by muse, mutect2, varscan2
- FOXG1 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100486423; called by muse, mutect2, varscan2
- GAPDHS | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 110/163 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV99722167; called by muse, mutect2, varscan2
- GC | c.923T>A p.V308D | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.125); catalogued as COSV99909283; called by muse, mutect2, varscan2
- GJA10 | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101005263; called by muse, mutect2, varscan2
- GNPTAB | c.2476A>G p.I826V | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs553711125, COSV100171489; called by muse, mutect2, varscan2
- GPR139 | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100429540, COSV58504859; called by muse, mutect2, varscan2
- GPRC5A | c.959A>T p.Y320F | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99185503; called by muse, mutect2, varscan2
- GRM8 | c.2103C>A p.S701R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.652); catalogued as COSV100279331, COSV58836046; called by muse, mutect2, varscan2
- GSC2 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99324011; called by muse, mutect2, varscan2
- GSPT2 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); catalogued as rs1326085630, COSV100467836; called by muse, mutect2, varscan2
- HECTD4 | c.7275C>G p.D2425E | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV101106328; called by muse, mutect2, varscan2
- HK3 | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99457531; called by muse, mutect2, varscan2
- HNRNPL | c.807G>C p.K269N | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99669834; called by muse, mutect2
- HSPA9 | c.854A>T p.H285L | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as COSV99785171; called by muse, mutect2, varscan2
- HSPA9 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as rs1390694256, COSV99785173; called by muse, mutect2, varscan2
- HSPB1 | c.413T>G p.F138C | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99949122; called by muse, mutect2, varscan2
- HVCN1 | c.106C>G p.H36D | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99656953; called by muse, mutect2, varscan2
- IGSF9 | c.1727C>T p.P576L (on ENST00000368094 / NM_001135050.2; = p.P560L on NM_020789.4) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100829559, COSV63640285; called by muse, mutect2, varscan2
- IL12B | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.667); catalogued as COSV51454651, COSV99180308; called by muse, mutect2, varscan2
- ITGA11 | c.2674G>A p.V892I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV100240635; called by muse, mutect2, varscan2
- ITGB4 | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52322724, COSV99563100; called by muse, mutect2, varscan2
- ITIH4 | c.862A>T p.R288W | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99818704; called by muse, mutect2, varscan2
- JPT2 | c.455A>T p.K152M | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV99935923; called by muse, mutect2, varscan2
- KBTBD12 | c.503A>G p.E168G | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100675321; called by muse, mutect2, varscan2
- KCNB2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV73049334; called by muse, mutect2
- KCNH2 | c.2282C>A p.T761K | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100058696; called by muse, mutect2, varscan2
- KDM4C | c.2222G>T p.W741L | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184601; called by muse, mutect2, varscan2
- KDM5B | c.2840G>T p.G947V | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV52507434, COSV99349838; called by muse, mutect2, varscan2
- KDM6A | c.3736G>C p.A1246P | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as COSV100937750; called by muse, mutect2, varscan2
- KIF21B | c.3020A>G p.E1007G | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100143156; called by muse, mutect2, varscan2
- KLF10 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53435507; called by muse, mutect2, varscan2
- KLHL1 | c.171del p.S59Afs*7 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as COSV64766964, COSV64777483; called by mutect2, pindel, varscan2
- KLHL5 | c.2248G>T p.V750F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99784613; called by muse, mutect2, varscan2
- KRT33A | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV99144762; called by muse, mutect2, varscan2
- LACRT | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV99143786; called by muse, mutect2, varscan2
- LAMP3 | c.1051C>A p.L351M | Missense Mutation (SNP) | VAF 124/768 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99660229; called by muse, mutect2, varscan2
- LMX1A | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99671364; called by muse, mutect2, varscan2
- LRRC7 | c.669G>T p.Q223H (on ENST00000651989 / NM_001370785.2; = p.Q190H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV99223615; called by muse, mutect2, varscan2
- LRRK2 | c.7154G>A p.G2385E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100108575; called by muse, mutect2, varscan2
- M6PR | c.629A>T p.Y210F | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs1427290080, COSV99134057; called by muse, mutect2, varscan2
- MAGEA8 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99674311; called by muse, mutect2, varscan2
- MAGEB18 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV100305231; called by muse, mutect2, varscan2
- MAGEC3 | c.1529G>A p.G510D | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100024583; called by muse, mutect2, varscan2
- MARK1 | c.2096C>G p.S699C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100856956, COSV65067038; called by muse, mutect2, varscan2
- MDGA2 | c.2037C>G p.N679K (on ENST00000399232 / NM_001113498.2; = p.N381K on NM_182830.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.098); catalogued as COSV100636049, COSV62102271; called by muse, mutect2, varscan2
- MGAM | c.3538G>C p.G1180R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101527328, COSV101527769; called by muse, mutect2, varscan2
- MGAT2 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 68/235 reads (29%) | catalogued as COSV100023383; called by muse, mutect2, varscan2
- MROH1 | c.987G>C p.M329I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100395452; called by muse, mutect2, varscan2
- MS4A6A | c.739A>T p.T247S | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100124466; called by muse, varscan2
- MSC | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV57696409; called by muse, mutect2, varscan2
- MUC17 | c.938G>T p.S313I | Missense Mutation (SNP) | VAF 178/382 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV100071020, COSV60298928; called by muse, mutect2, varscan2
- MYF5 | c.576T>C p.N192= | Splice Region (SNP) | VAF 55/160 reads (34%) | catalogued as COSV99953060; called by muse, mutect2, varscan2
- MYH7 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as CM031265, COSV100805538; called by muse, mutect2, varscan2
- MYH9 | c.891C>G p.Y297* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV53390999; called by muse, mutect2, varscan2
- MYO16 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99193394; called by muse, mutect2, varscan2
- MYT1L | c.2938G>T p.A980S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV101216700; called by muse, mutect2, varscan2
- NBEA | c.5413G>T p.V1805L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.437); catalogued as COSV100075574; called by muse, mutect2, varscan2
- NCS1 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV100969837; called by muse, mutect2, varscan2
- NDST4 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs145767700; called by muse, mutect2, varscan2
- NLGN4X | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220178708, COSV52006855, COSV99319329, COSV99321108; called by muse, mutect2, varscan2
- NME8 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 45/130 reads (35%) | catalogued as COSV99552600; called by muse, mutect2, varscan2
- NOL4 | c.1612G>T p.V538F | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.219); catalogued as COSV52354798, COSV99304513; called by muse, mutect2, varscan2
- NR5A1 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV101007614; called by muse, mutect2
- NRDC | c.2261C>T p.T754I | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); catalogued as COSV100702919; called by muse, mutect2, varscan2
- NRXN1 | c.4432T>C p.*1478Rext*10 | Nonstop Mutation (SNP) | VAF 29/138 reads (21%) | catalogued as COSV100639429; called by muse, mutect2, varscan2
- NSG2 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100292662, COSV57457448; called by muse, mutect2, varscan2
- NT5M | c.545-2A>T p.X182_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101198525; called by muse, mutect2, varscan2
- NTNG1 | c.417C>G p.S139R | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV99634888; called by muse, mutect2, varscan2
- NUBPL | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV55264867, COSV99808918; called by muse, mutect2, varscan2
- OBSCN | c.9872C>T p.A3291V | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.455); catalogued as rs745310805, COSV99470675; called by muse, mutect2, varscan2
- OBSCN | c.23902C>G p.R7968G | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as COSV100799997; called by muse, mutect2, varscan2
- OR10S1 | c.996G>C p.*332Yext*? | Nonstop Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV101602436, COSV101602449; called by muse, mutect2, varscan2
- OR14K1 | c.515T>A p.L172Q | Missense Mutation (SNP) | VAF 169/371 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV99314888; called by muse, mutect2, varscan2
- OR2M4 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 33/188 reads (18%) | catalogued as COSV100140903; called by muse, mutect2, varscan2
- OR4C12 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100078090; called by muse, mutect2, varscan2
- OR4C13 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.177); catalogued as rs375399263, COSV101634128; called by muse, mutect2, varscan2
- OR4D6 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV100271516, COSV100271805; called by muse, mutect2, varscan2
- OR51B6 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100970202, COSV66512168; called by muse, mutect2, varscan2
- OR52N5 | c.89G>T p.R30I | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100399539; called by muse, mutect2, varscan2
- OR5AR1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100265515; called by muse, mutect2, varscan2
- OR5D14 | c.503T>G p.L168* | Nonsense Mutation (SNP) | VAF 62/210 reads (30%) | catalogued as COSV100161970; called by muse, mutect2, varscan2
- OR6T1 | c.467T>G p.V156G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100189628; called by muse, mutect2, varscan2
- OR6X1 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs751203139, COSV100020394; called by muse, mutect2, varscan2
- OSBPL11 | c.1313A>G p.E438G | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99953866; called by muse, mutect2, varscan2
- OTOF | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759954218, COSV99716131; called by muse, mutect2, varscan2
- OVCH1 | c.2931G>T p.E977D | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100548162; called by muse, mutect2, varscan2
- PABPC1 | c.1389T>A p.F463L | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100589276; called by muse, mutect2
- PANX3 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs267602763, COSV99421084; called by muse, mutect2, varscan2
- PAPOLB | c.1136T>C p.L379P | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV101271185; called by muse, mutect2, varscan2
- PAPPA | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 82/146 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100072514; called by muse, mutect2, varscan2
- PAPPA2 | c.1678C>G p.R560G | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV100866390, COSV62776538; called by muse, mutect2, varscan2
- PAX9 | c.438C>G p.H146Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as rs757996388, COSV100825621, COSV100825882; called by muse, mutect2, varscan2
- PBXIP1 | c.2132G>A p.S711N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV100869970; called by muse, mutect2, varscan2
- PCCA | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778689888, COSV100886370; called by muse, mutect2, varscan2
- PCDH15 | c.1540T>A p.Y514N | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100213072; called by muse, mutect2, varscan2
- PCDHA8 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.973); catalogued as rs1554139363, COSV100968879, COSV65323689; called by muse, mutect2, varscan2
- PCSK5 | c.1755A>T p.P585= | Splice Region (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100949294; called by muse, mutect2, varscan2
- PDE6H | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV99843901; called by muse, mutect2, varscan2
- PDE6H | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV56760748, COSV99843902; called by muse, mutect2, varscan2
- PGPEP1 | c.217G>C p.V73L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV99416384; called by muse, mutect2, varscan2
- PHC1 | c.2778T>G p.H926Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99134055; called by muse, mutect2, varscan2
- PIP | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs547073010, COSV52120454, COSV99344236; called by muse, mutect2, varscan2
- PLA2G4D | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV51820906, COSV99299125; called by muse, mutect2, varscan2
- PNPT1 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.371); catalogued as COSV99569463; called by muse, mutect2, varscan2
- POM121L12 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV101374805; called by muse, mutect2, varscan2
- POMGNT2 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100767871; called by muse, mutect2, varscan2
- PRAME | c.672G>C p.K224N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as COSV101286989, COSV67161739; called by muse, mutect2, varscan2
- PRAMEF14 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100577251; called by muse, mutect2, varscan2
- PSEN2 | c.156C>G p.N52K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100422696; called by muse, mutect2
- PTCHD4 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.901); catalogued as COSV100259609; called by muse, mutect2, varscan2
- RAD51B | c.452+2T>C p.X151_splice | Splice Site (SNP) | VAF 24/81 reads (30%) | catalogued as rs1464701988, COSV101184740; called by muse, mutect2, varscan2
- RFX4 | c.1477G>A p.V493I (on ENST00000392842 / NM_213594.3; = p.V399I on NM_032491.6) | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57574251, COSV99985201; called by muse, mutect2, varscan2
- RNF138 | c.613A>T p.R205* | Nonsense Mutation (SNP) | VAF 59/158 reads (37%) | catalogued as COSV99857299; called by muse, mutect2, varscan2
- RPH3A | c.499C>A p.P167T (on ENST00000389385 / NM_001143854.2; = p.P163T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101231749; called by muse, mutect2, varscan2
- RPS6KC1 | c.1835T>C p.L612P | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs1013094895, COSV100873727; called by muse, mutect2, varscan2
- SCN10A | c.4709C>A p.T1570K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs772484960, COSV101479190, COSV71860989; called by muse, mutect2, varscan2
- SCRN3 | c.939A>G p.I313M | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV55808034; called by muse, mutect2, varscan2
- SFTPB | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV100667074; called by muse, mutect2
- SH2B2 | c.1594G>C p.D532H | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV100159180; called by muse, mutect2, varscan2
- SHE | c.421A>T p.S141C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100495792; called by muse, mutect2, varscan2
- SHOX2 | c.695T>A p.F232Y (on ENST00000441443 / NM_006884.3; = p.F256Y on NM_003030.4) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV101273722; called by muse, mutect2, varscan2
- SIDT1 | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99332833; called by muse, mutect2, varscan2
- SIGLEC12 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.345); catalogued as COSV99388953; called by muse, mutect2, varscan2
- SIL1 | c.1137C>A p.C379* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as CM1312513, COSV99497507; called by muse, mutect2, varscan2
- SLC10A2 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99807462; called by muse, mutect2, varscan2
- SLC16A1 | c.28G>T p.G10* | Nonsense Mutation (SNP) | VAF 22/36 reads (61%) | catalogued as COSV100855754; called by muse, mutect2, varscan2
- SLC22A25 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs201958778, COSV100123346, COSV60594994; called by muse, mutect2, varscan2
- SLC23A2 | c.787G>T p.G263W | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100594674, COSV57776109; called by muse, mutect2, varscan2
- SLC35G5 | c.815A>C p.Y272S | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1224542180, COSV99643821; called by muse, mutect2, varscan2
- SLC41A2 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770644705, COSV99316000; called by muse, mutect2, varscan2
- SLC41A2 | c.1537-1G>T p.X513_splice | Splice Site (SNP) | VAF 51/176 reads (29%) | catalogued as COSV99316001; called by muse, mutect2, varscan2
- SLC4A1 | c.2185G>A p.V729M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775748758, COSV52262400, COSV52263082; called by muse, mutect2, varscan2
- SLC5A11 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1015585735, COSV100762616; called by muse, mutect2, varscan2
- SLC7A10 | c.807C>G p.I269M | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99471846; called by muse, mutect2, varscan2
- SLCO1C1 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV99858207; called by muse, mutect2, varscan2
- SLIT2 | c.2108A>T p.Q703L | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs778132485, COSV99879656; called by muse, mutect2
- SLITRK3 | c.1397A>G p.N466S | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53852129, COSV99578123; called by muse, mutect2
- SLITRK4 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 64/139 reads (46%) | catalogued as COSV100567070, COSV100567422, COSV62025137; called by muse, mutect2, varscan2
- SMARCA5 | c.2560A>C p.I854L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99303313; called by muse, mutect2, varscan2
- SON | c.5501A>G p.H1834R | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs1279391009, COSV51672515; called by muse, mutect2, varscan2
- SORBS2 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.841); catalogued as COSV53022259; called by muse, mutect2
- SPANXN1 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100979251; called by muse, mutect2, varscan2
- SPATA31E1 | c.3825C>A p.H1275Q | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs35501442, COSV100349685; called by muse, mutect2, varscan2
- STRIP1 | c.1760A>T p.K587M | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874021; called by muse, mutect2, varscan2
- STYK1 | c.805G>T p.G269* | Nonsense Mutation (SNP) | VAF 79/256 reads (31%) | catalogued as COSV99311480; called by muse, mutect2, varscan2
- SWT1 | c.2499C>G p.I833M | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV100832951; called by muse, mutect2, varscan2
- TBC1D28 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV100560875; called by muse, mutect2, varscan2
- TBC1D8B | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs768127642, COSV52183370, COSV99343724; called by muse, mutect2, varscan2
- TEX45 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV64464148; called by muse, mutect2, varscan2
- THEMIS | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.095); catalogued as COSV100965189, COSV64070823; called by muse, mutect2, varscan2
- THSD7B | c.3794G>C p.C1265S (on ENST00000272643; = p.C1263S on NM_001316349.2) | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99741894; called by muse, mutect2, varscan2
- TMEM174 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99703695; called by muse, mutect2, varscan2
- TMEM63B | c.1208A>C p.H403P | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV99440809; called by muse, mutect2, varscan2
- TNS4 | c.1444T>C p.S482P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99563454; called by muse, mutect2, varscan2
- TPO | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767922886, COSV100219300; called by muse, mutect2, varscan2
- TRAPPC12 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100159920; called by muse, mutect2, varscan2
- TRAPPC9 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV101226297; called by muse, mutect2, varscan2
- TRPC4 | c.1651G>T p.G551C | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100155407; called by muse, mutect2, varscan2
- TRPM1 | c.4310C>A p.S1437Y | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV56636831, COSV99855109; called by muse, mutect2, varscan2
- TTLL5 | c.2004T>G p.N668K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs1484812652, COSV100088399, COSV54033650; called by muse, mutect2, varscan2
- TTN | c.73808A>G p.N24603S (on ENST00000591111; = p.N17179S on NM_003319.4) | Missense Mutation (SNP) | VAF 109/188 reads (58%) | PolyPhen benign (0.164); catalogued as COSV100588455; called by muse, mutect2, varscan2
- TTN | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 65/108 reads (60%) | PolyPhen probably damaging (0.999); catalogued as COSV100588460, COSV60218568; called by muse, mutect2, varscan2
- UBA52 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV99723597; called by muse, mutect2, varscan2
- UBASH3B | c.902T>A p.L301* | Nonsense Mutation (SNP) | VAF 78/290 reads (27%) | catalogued as COSV99416405; called by muse, mutect2
- UBE3C | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100779617; called by muse, mutect2, varscan2
- UNC13A | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99406721; called by muse, mutect2, varscan2
- UNC5D | c.2461C>T p.Q821* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as COSV99770973; called by muse, mutect2, varscan2
- USH2A | c.3191T>A p.V1064D | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100227387; called by muse, mutect2, varscan2
- USP25 | c.1209-2A>T p.X403_splice | Splice Site (SNP) | VAF 30/83 reads (36%) | catalogued as COSV99582895; called by muse, mutect2, varscan2
- VEPH1 | c.1096C>A p.Q366K | Missense Mutation (SNP) | VAF 230/361 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100747224; called by muse, mutect2, varscan2
- VEPH1 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100747226; called by muse, mutect2, varscan2
- VPS52 | c.1343A>T p.H448L | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV101460399; called by muse, mutect2, varscan2
- WASHC5 | c.2803G>T p.A935S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV100572365; called by muse, mutect2, varscan2
- WDR47 | c.805G>T p.V269F | Missense Mutation (SNP) | VAF 100/210 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV100728199; called by muse, mutect2, varscan2
- WIPI2 | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV56587541; called by muse, mutect2
- ZBBX | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 59/460 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs200369263, COSV100282839; called by muse, mutect2, varscan2
- ZBTB1 | c.1171C>G p.R391G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as COSV100703847, COSV62439049; called by muse, mutect2, varscan2
- ZBTB41 | c.1085A>G p.Q362R | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100962707; called by muse, mutect2, varscan2
- ZBTB7C | c.1209G>T p.R403S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100134180; called by muse, mutect2, varscan2
- ZNF302 | c.1020A>T p.E340D (on ENST00000627982; = p.E261D on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV101416416; called by muse, mutect2, varscan2
- ZNF536 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100834501; called by muse, mutect2, varscan2
- ZNF536 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV100834502; called by muse, mutect2, varscan2
- ZNF707 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100690475; called by muse, mutect2
- ZNF709 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as COSV101172052; called by muse, mutect2, varscan2
- ZNF75D | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100883533, COSV100883696; called by muse, mutect2, varscan2
- ZNF804B | c.1137G>T p.R379S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.212); catalogued as COSV60817290, COSV60823975; called by muse, mutect2
- ZP2 | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 38/147 reads (26%) | catalogued as COSV99559060; called by muse, mutect2, varscan2
- C10orf71 | c.561C>A p.C187* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- COL6A3 | c.953_969del p.E318Afs*4 | Frame Shift Del (DEL) | VAF 17/31 reads (55%) | called by mutect2, pindel, varscan2
- GZMA | c.561del p.F187Lfs*4 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | called by pindel, varscan2
- IGKV1-9 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 161/393 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- IGKV1-9 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 159/393 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- LIPI | c.1268del p.L423* | Frame Shift Del (DEL) | VAF 47/185 reads (25%) | called by mutect2, pindel, varscan2
- MAG | c.1332del p.F444Lfs*8 | Frame Shift Del (DEL) | VAF 42/312 reads (13%) | called by mutect2, pindel, varscan2
- NPAP1 | c.1337_1338del p.T446Nfs*6 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | called by pindel, varscan2
- OSBPL11 | c.79_80del p.T27Pfs*13 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel*, varscan2*
- PALMD | c.131dup p.A45Gfs*42 | Frame Shift Ins (INS) | VAF 36/106 reads (34%) | called by mutect2, pindel, varscan2
- PER2 | c.152_158delinsA p.R51_S53delinsQ | In Frame Del (DEL) | VAF 15/48 reads (31%) | called by pindel, varscan2*
- PKHD1 | c.3624del p.L1209Wfs*11 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- PRAMEF6 | c.1284G>T p.W428C | Missense Mutation (SNP) | VAF 152/777 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); called by muse, mutect2
- SYNRG | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB11 | c.2757C>T p.T919= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV99791263; called by muse, mutect2, varscan2
- ADAR | c.3286C>A p.R1096= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as CM041233, COSV52722260, COSV99425292; called by muse, mutect2, varscan2
- ARMC5 | c.1467C>G p.A489= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99192297; called by muse, mutect2, varscan2
- ATAD2 | c.2406A>T p.G802= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV99783861; called by muse, mutect2, varscan2
- ATP8B3 | c.771C>A p.A257= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV100033766; called by muse, mutect2, varscan2
- C12orf66 | c.1056G>A p.L352= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as COSV100320477; called by muse, mutect2, varscan2
- CBLN2 | c.150G>T p.R50= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99504035; called by muse, mutect2, varscan2
- CCT6B | c.903C>T p.S301= | Silent (SNP) | VAF 61/236 reads (26%) | catalogued as COSV58492219; called by muse, mutect2, varscan2
- CDH10 | c.2016C>A p.I672= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as rs201737578, COSV52573402, COSV52582613; called by muse, mutect2, varscan2
- CDH10 | c.264A>T p.S88= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as COSV100049558; called by muse, mutect2, varscan2
- CFAP43 | c.2118C>T p.G706= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV99530250; called by muse, mutect2
- CFHR4 | c.1284C>T p.I428= (on ENST00000367416 / NM_001201551.2; = p.I182= on NM_006684.5) | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV99259085; called by muse, mutect2, varscan2
- CHRFAM7A | c.582C>T p.P194= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as rs762824692, COSV100241486; called by muse, mutect2, varscan2
- CMYA5 | c.5598A>G p.S1866= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as COSV101483693; called by muse, mutect2, varscan2
- COL4A3 | c.3987C>T p.S1329= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as COSV101169721; called by muse, mutect2, varscan2
- DCDC1 | c.3432G>A p.V1144= (on ENST00000597505 / NM_001367979.1; = p.V251= on NM_020869.3) | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100337707, COSV60304035; called by muse, mutect2, varscan2
- DENND5B | c.2028G>T p.R676= | Silent (SNP) | VAF 57/178 reads (32%) | catalogued as COSV60902111; called by muse, mutect2, varscan2
- DISP1 | c.1458G>A p.G486= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV52655264; called by muse, mutect2, varscan2
- DNAH11 | c.6990G>T p.V2330= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1351648363, COSV100176070; called by muse, mutect2, varscan2
- EARS2 | c.933C>A p.I311= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV101492135; called by muse, mutect2, varscan2
- EPPK1 | c.876G>C p.L292= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV101599702; called by muse, mutect2, varscan2
- FGF14 | c.438A>G p.K146= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV101083979; called by muse, mutect2, varscan2
- FLRT2 | c.1647C>A p.G549= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs35699071, COSV100419855; called by muse, mutect2, varscan2
- GPR142 | c.594G>C p.A198= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100170630; called by muse, mutect2, varscan2
- GPR31 | c.465C>T p.A155= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs1397830539, COSV100834092; called by muse, mutect2, varscan2
- H4C7 | c.294G>T p.L98= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99768982; called by muse, mutect2, varscan2
- HAO1 | c.372G>A p.E124= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs1300620172, COSV101113091; called by muse, mutect2, varscan2
- HUWE1 | c.9948A>T p.A3316= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV99469993; called by muse, mutect2, varscan2
- KCNT1 | c.57C>T p.G19= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as rs1245480933, COSV100039704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1109 | c.2496T>C p.P832= | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as COSV99145320; called by muse, mutect2, varscan2
- KIF26B | c.3267C>T p.C1089= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV100831442; called by muse, mutect2, varscan2
- KLK2 | c.300C>A p.L100= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100319780; called by muse, mutect2, varscan2
- KMT2A | c.3177A>G p.S1059= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV100627503; called by muse, mutect2, varscan2
- KMT2C | c.10875C>T p.P3625= | Silent (SNP) | VAF 51/105 reads (49%) | catalogued as rs981997486, COSV100064356; called by muse, mutect2, varscan2
- LIM2 | c.258C>T p.F86= (on ENST00000596399 / NM_001161748.2; = p.F128= on NM_030657.4) | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs201810597, COSV55742362, COSV99702170; called by muse, mutect2, varscan2
- LRRC7 | c.597C>A p.V199= (on ENST00000651989 / NM_001370785.2; = p.V166= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV50670979; called by muse, mutect2, varscan2
- MARCO | c.276G>T p.P92= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs750963747, COSV100503060; called by muse, mutect2, varscan2
- OR2L3 | c.852C>A p.L284= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as COSV100741881; called by muse, mutect2, varscan2
- OR2M4 | c.45G>T p.L15= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as rs1325590349, COSV100140968; called by muse, mutect2, varscan2
- OR2T4 | c.723C>T p.I241= | Silent (SNP) | VAF 65/308 reads (21%) | catalogued as COSV63543507; called by muse, mutect2, varscan2
- OR4C12 | c.726C>A p.I242= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs782776432, COSV100078086; called by muse, mutect2, varscan2
- OR5T1 | c.648C>A p.G216= | Silent (SNP) | VAF 55/229 reads (24%) | catalogued as COSV100478618; called by muse, mutect2, varscan2
- PCDH11X | c.3648G>T p.V1216= | Silent (SNP) | VAF 66/133 reads (50%) | catalogued as COSV100006856; called by muse, mutect2, varscan2
- PCDHA1 | c.1746G>T p.P582= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as COSV65373311, COSV65377333; called by muse, mutect2, varscan2
- PCDHA12 | c.204C>T p.S68= | Silent (SNP) | VAF 64/159 reads (40%) | catalogued as COSV100246802; called by muse, mutect2, varscan2
- PCDHB7 | c.2316G>A p.L772= | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as rs774018894, COSV99175167; called by muse, mutect2, varscan2
- PCDHGA1 | c.2010C>T p.D670= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs1420389841, COSV100965916; called by muse, mutect2, varscan2
- PDZRN3 | c.1986C>T p.Y662= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs142044798, COSV104376567; called by muse, mutect2, varscan2
- POTEH | c.378T>A p.S126= | Silent (SNP) | VAF 94/540 reads (17%) | catalogued as COSV100624597; called by muse, varscan2
- PRC1 | c.1740T>C p.S580= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs755126459, COSV100726991; called by muse, mutect2, varscan2
- PTGDR | c.630G>T p.L210= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV100035378; called by muse, mutect2, varscan2
- RELN | c.495C>G p.G165= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as COSV100631828, COSV100632056; called by muse, mutect2, varscan2
- SALL1 | c.3720G>T p.A1240= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs185996794, COSV51757256, COSV99171462; called by muse, mutect2, varscan2
- SERPINA4 | c.339T>C p.S113= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100096842; called by muse, mutect2, varscan2
- SGSM3 | c.1677C>A p.L559= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99960054; called by muse, mutect2, varscan2
- SH3D21 | c.1444C>T p.L482= (on ENST00000453908 / NM_001162530.2; = p.L371= on NM_024676.5) | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as COSV99583840; called by muse, mutect2, varscan2
- SLIT2 | c.2106C>T p.I702= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV56580663, COSV99879655; called by muse, mutect2
- SUPT16H | c.396G>A p.K132= | Silent (SNP) | VAF 56/199 reads (28%) | catalogued as COSV53523279, COSV99359513; called by muse, mutect2, varscan2
- SYNE2 | c.8002T>C p.L2668= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as COSV100646339; called by muse, mutect2, varscan2
- TBX22 | c.243C>A p.G81= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100960552; called by muse, mutect2, varscan2
- TNR | c.852G>A p.E284= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV99686730; called by muse, mutect2, varscan2
- TRIM10 | c.210G>T p.R70= | Silent (SNP) | VAF 57/195 reads (29%) | catalogued as COSV100938761; called by muse, mutect2, varscan2
- TRIM42 | c.1299C>A p.A433= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV53883374, COSV99647823; called by muse, mutect2, varscan2
- TSC22D2 | c.2124A>G p.E708= | Silent (SNP) | VAF 15/214 reads (7%) | catalogued as COSV100721164; called by muse, mutect2
- TYR | c.1140T>C p.S380= | Silent (SNP) | VAF 56/171 reads (33%) | catalogued as COSV99632623; called by muse, mutect2, varscan2
- VEPH1 | c.324C>T p.I108= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as rs773384515, COSV62882221; called by muse, mutect2, varscan2
- ZNF438 | c.1348C>T p.L450= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV100061004; called by muse, mutect2, varscan2
- ZNF479 | c.162C>G p.S54= | Silent (SNP) | VAF 50/376 reads (13%) | catalogued as rs746915175, COSV100482338; called by muse, varscan2
- ZNF875 | c.1821T>C p.H607= | Silent (SNP) | VAF 126/207 reads (61%) | catalogued as rs566316422, COSV100182960; called by muse, mutect2, varscan2
- AL590867.2 | n.184C>A | RNA (SNP) | VAF 72/188 reads (38%) | called by muse, mutect2, varscan2
- FOLH1B | n.2056G>T | RNA (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671004 G>T | 3'Flank (SNP) | VAF 130/271 reads (48%) | called by muse, mutect2, varscan2
- PREP | c.-148G>A | 5'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- SPATA8 | n.877C>T | RNA (SNP) | VAF 37/117 reads (32%) | catalogued as COSV100138834; called by muse, mutect2, varscan2
- TTN | c.34264+2754G>C | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as COSV100588459; called by muse, mutect2, varscan2
- VSIG4 | chrX:66018971 G>T | 3'Flank (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- XIST | n.9650C>T | RNA (SNP) | VAF 11/31 reads (35%) | catalogued as rs756919434; called by muse, mutect2, varscan2
